Somatic mutation profile of tumor specimen TCGA-CV-5440-01A (aliquot TCGA-CV-5440-01A-01D-1512-08) from TCGA case TCGA-CV-5440, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 52.6 years (19,197 days).
Specimen TCGA-CV-5440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c9bc3f4-ebe1-49dc-ade7-e4c2f1baef0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5440-11A (Solid Tissue Normal), aliquot TCGA-CV-5440-11A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/113a91ae-092e-455b-91ff-fbc7e3f586b4

The open-access MAF lists 119 somatic variants for this specimen: 87 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 2, Intron 2, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 36/44 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 39/86 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770014944, COSV99698111; called by muse, mutect2, varscan2
- ADAM32 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV101165188; called by muse, mutect2
- ALPK3 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99360016; called by muse, varscan2
- ANGEL2 | c.339G>C p.M113I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100853903; called by muse, mutect2, varscan2
- ANKRD11 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV56374078, COSV99968018; called by muse, mutect2, varscan2
- ASPA | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99559095; called by muse, mutect2, varscan2
- ATP11A | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99367160; called by muse, mutect2, varscan2
- ATXN3 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100515068; called by muse, mutect2, varscan2
- BRCA2 | c.6313A>G p.I2105V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs397507368, COSV101203826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPER2 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV100390482; called by muse, mutect2, varscan2
- CDAN1 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as COSV99141036; called by muse, mutect2, varscan2
- CEMIP2 | c.2699G>T p.G900V | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1171748147, COSV100987053; called by muse, mutect2, varscan2
- CFAP70 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV60284375; called by muse, mutect2, varscan2
- CNNM1 | c.1604T>A p.V535E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV100763749; called by muse, mutect2, varscan2
- COL15A1 | c.1984C>G p.P662A | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV100897302; called by muse, mutect2, varscan2
- CSPP1 | c.3307G>T p.E1103* (on ENST00000676605; = p.E1062* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99137938; called by muse, mutect2, varscan2
- DENND1A | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs776432167, COSV101010340, COSV101010771; called by muse, mutect2, varscan2
- DLG2 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV99711947; called by muse, mutect2, varscan2
- DNMBP | c.4252C>G p.L1418V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100142870; called by muse, mutect2, varscan2
- DNMBP | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as COSV60622231; called by muse, mutect2, varscan2
- DNMBP | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100142875; called by muse, mutect2, varscan2
- DOCK11 | c.4079C>T p.S1360L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99352608; called by muse, mutect2, varscan2
- GBP6 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs1456755717, COSV100969436, COSV100969734; called by muse, mutect2, varscan2
- GDPGP1 | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100291980; called by muse, mutect2, varscan2
- GHRL | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV99813861; called by muse, mutect2, varscan2
- GPRC6A | c.1453C>A p.H485N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as COSV100113922; called by muse, mutect2, varscan2
- HOXB7 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99493844; called by muse, mutect2, varscan2
- KCNQ4 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100714251; called by muse, mutect2, varscan2
- KLHDC8B | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV100234042; called by muse, mutect2, varscan2
- LAMA3 | c.9275G>A p.G3092E (on ENST00000313654 / NM_198129.4; = p.G1483E on NM_000227.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1383006206, COSV52536031; called by muse, mutect2, varscan2
- LIMK1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs371905268, COSV100282931; called by muse, mutect2, varscan2
- LRP4 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066106; called by muse, mutect2, varscan2
- MGA | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV54949467; called by mutect2, varscan2
- MMEL1 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56523123, COSV99983102; called by muse, mutect2, varscan2
- MORF4L2 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100846339, COSV64610803; called by muse, mutect2, varscan2
- MTX3 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV101560463; called by muse, mutect2, varscan2
- MUC17 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1378790871, COSV100071163; called by muse, mutect2, varscan2
- MYH3 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99877568; called by muse, mutect2
- NAV3 | c.4901T>C p.I1634T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1208413675, COSV99885969; called by muse, mutect2, varscan2
- NOX3 | c.1199C>G p.P400R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99342565; called by muse, mutect2, varscan2
- NOX3 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99342568; called by muse, mutect2, varscan2
- OR4C12 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100078168, COSV100078727; called by muse, mutect2, varscan2
- OR5K2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs1048909703, COSV71143150, COSV71143440; called by muse, mutect2, varscan2
- PASK | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777921319, COSV99298451, COSV99298652; called by muse, mutect2, varscan2
- PCCB | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV99291004; called by muse, mutect2, varscan2
- PDE1C | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100370474; called by muse, mutect2, varscan2
- PEX14 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.399); catalogued as COSV100749954; called by muse, mutect2, varscan2
- PGBD2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV100251812; called by muse, mutect2, varscan2
- PPFIA2 | c.1466C>G p.A489G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.397); catalogued as COSV100331261; called by muse, mutect2, varscan2
- PRDM10 | c.1673G>T p.C558F | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV100456515; called by muse, mutect2, varscan2
- PSMB10 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99862786; called by muse, mutect2, varscan2
- RAB3A | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV99717874; called by muse, mutect2, varscan2
- RET | c.1010A>T p.E337V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100392003; called by muse, mutect2, varscan2
- RIMS2 | c.2015T>C p.L672P (on ENST00000666250 / NM_001348490.2; = p.L480P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99154152, COSV99170085; called by muse, mutect2, varscan2
- RIMS2 | c.2882G>A p.R961Q (on ENST00000666250 / NM_001348490.2; = p.R769Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); catalogued as rs368813886; called by muse, mutect2, varscan2
- RNF133 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100411404, COSV57387212; called by muse, mutect2, varscan2
- SEC24A | c.2716C>G p.L906V | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs759797682, COSV101295009; called by muse, mutect2, varscan2
- SLC12A5 | c.1471G>A p.E491K (on ENST00000454036 / NM_001134771.2; = p.E468K on NM_020708.5) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs564134718, COSV54787704; called by mutect2, varscan2
- SNX30 | c.664A>G p.M222V | Missense Mutation (SNP) | VAF 104/128 reads (81%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100953712; called by muse, mutect2, varscan2
- SPG11 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99967856; called by muse, mutect2, varscan2
- STAT4 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV100635927, COSV61830048; called by muse, mutect2, varscan2
- TFCP2L1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.631); catalogued as rs137971940; called by muse, mutect2, varscan2
- TIAL1 | c.447+2T>A p.X149_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100958317; called by muse, mutect2, varscan2
- TMEM14A | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99275815; called by muse, mutect2, varscan2
- TOX | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as rs1563395438, COSV100812533; called by muse, mutect2, varscan2
- TP63 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.536); catalogued as CD053011, CM147330, COSV99285067; called by muse, mutect2, varscan2
- TTN | c.41764G>C p.E13922Q (on ENST00000591111; = p.E6498Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | PolyPhen probably damaging (0.997); catalogued as COSV100589826, COSV60412499; called by muse, mutect2, varscan2
- UGT2B4 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100522122; called by muse, mutect2, varscan2
- WASHC2C | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV100313747; called by muse, mutect2
- WNK3 | c.5026C>A p.Q1676K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV100670620; called by muse, mutect2, varscan2
- XAB2 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs4134865; called by muse, mutect2, varscan2
- ZNF227 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100480139; called by muse, mutect2, varscan2
- ZNF43 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100731631; called by muse, mutect2, varscan2
- ZNF510 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141866339, COSV99793695; called by muse, mutect2, varscan2
- ZNF592 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100245626, COSV55439627; called by muse, mutect2, varscan2
- ZNF804A | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100165828; called by muse, mutect2, varscan2
- AC024598.1 | c.1279del p.Q427Kfs*4 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.983T>C p.F328S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HMCN1 | c.4229_4230del p.V1410Efs*25 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by pindel, varscan2
- KMT2D | c.7535_7550del p.S2512Ifs*26 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by mutect2, varscan2
- NRIP1 | c.1764del p.E589Kfs*3 | Frame Shift Del (DEL) | VAF 83/178 reads (47%) | called by mutect2, pindel, varscan2
- SMC5 | c.2104dup p.T702Nfs*28 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- TNS3 | c.2615_2627del p.L872Pfs*129 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- TRPV2 | c.335-5_353del p.X112_splice | Splice Site (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- CALU | c.774C>T p.I258= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs1293452801, COSV99975381; called by muse, mutect2, varscan2
- CCHCR1 | c.420A>T p.R140= | Silent (SNP) | VAF 196/260 reads (75%) | catalogued as COSV100883800; called by muse, mutect2, varscan2
- CD68 | c.30C>T p.A10= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1264574486, COSV99548648; called by muse, mutect2, varscan2
- CFAP70 | c.2148G>A p.L716= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100160055, COSV100160737; called by muse, mutect2, varscan2
- CHD4 | c.4437C>G p.V1479= (on ENST00000357008 / NM_001363606.2; = p.V1492= on NM_001273.5) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100537155; called by muse, mutect2, varscan2
- CHSY3 | c.594C>T p.F198= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100518252; called by muse, mutect2, varscan2
- CRTC1 | c.213C>T p.I71= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs779827394, COSV100118945; called by muse, mutect2, varscan2
- EIF3H | c.681A>G p.K227= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV99411334; called by muse, mutect2, varscan2
- FBXO46 | c.1455C>T p.F485= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs766581156, COSV100479877; called by muse, mutect2, varscan2
- FNDC3A | c.1581G>A p.V527= (on ENST00000492622 / NM_001079673.2; = p.V471= on NM_014923.5) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101256563; called by muse, mutect2, varscan2
- GLP2R | c.1107C>G p.L369= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV99301426, COSV99301631; called by muse, mutect2, varscan2
- HID1 | c.1593C>T p.F531= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100585918; called by muse, mutect2, varscan2
- HLTF | c.585T>C p.Y195= | Silent (SNP) | VAF 47/62 reads (76%) | catalogued as COSV100026659; called by muse, mutect2, varscan2
- MDC1 | c.267C>T p.L89= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV64524441; called by muse, mutect2, varscan2
- MICAL2 | c.5724G>A p.E1908= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV56287929, COSV99811296; called by muse, mutect2, varscan2
- MRTFB | c.663A>G p.P221= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs766043027, COSV100370753; called by muse, mutect2, varscan2
- PACRG | c.507C>G p.L169= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100432941; called by muse, mutect2, varscan2
- PAN2 | c.594A>T p.G198= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99228032; called by muse, mutect2, varscan2
- PKD1 | c.2766C>G p.L922= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99236955, COSV99238142; called by muse, mutect2, varscan2
- PTPN21 | c.2481G>A p.K827= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100161357; called by muse, mutect2, varscan2
- RASSF4 | c.342G>T p.V114= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100436665; called by muse, mutect2, varscan2
- RNF17 | c.4758C>G p.L1586= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs747455621, COSV99691875, COSV99694395; called by muse, mutect2
- SECISBP2L | c.804T>C p.I268= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99959702; called by muse, mutect2, varscan2
- SLC6A13 | c.817C>T p.L273= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- SYK | c.1483C>T p.L495= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV101002218; called by muse, mutect2, varscan2
- TLE4 | c.1563G>A p.K521= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99510846; called by muse, mutect2, varscan2
- WASHC5 | c.2151C>T p.R717= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs766145087, COSV100572410; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169765040 C>G | 3'Flank (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- ANKRD10 | c.456-860A>T | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99941001; called by muse, mutect2, varscan2
- KCNQ2 | c.1118+38C>A | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100609242; called by muse, mutect2, varscan2
- SNORD116-3 | n.60G>C | RNA (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- TPI1 | c.*276C>T | 3'UTR (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99222764; called by muse, mutect2, varscan2
